Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4758, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4758-01A (Primary Tumor).

[page 1 of 2]
...

Clinical Diagnosis & History:

Right renal mass; right partial nephrectomy.

Specimens Submitted:

1: SP: Right renal tumor [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- [REDACTED]
- [REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation labeled, "Right renal tumor, stitch marks deep margin and peritumoral fat", and consists of a 4 x 3.6 x 2.7 cm well-circumscribed orange-yellow hemorrhagic tumor mass, surrounded by a small rim of unremarkable red-tan renal parenchyma and perinephric fat. There is a suture at the deep margin. The deep margin is inked black. The peritumoral fat is also inked black. The tumor does not appear to extend through the renal capsule or into the fat, and is located 0.2 cm from the closest deep margin. Representative section of the tumor is frozen. [REDACTED] Representative sections of remainder of the specimen are submitted.

Summary of sections:

FSC-frozen section control

TM-tumor with deep margin

T-tumor

F-tumor with peri tumor fat

Summary of Sections:

Part 1: SP: Right renal tumor [REDACTED]

[page 2 of 2]
Block	Sect. Site	PCs
1	f	1
1	fsc	1
1	t	1
4	tdm	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. FAVOR CLEAR CELL TYPE. DEEP INKED MARGIN NEGATIVE. [REDACTED]
PERMANENT DIAGNOSIS: SEE FINAL DIAGNOSIS [REDACTED]

Source: NCI Genomic Data Commons file 46f70d1c-e8e0-4a19-83c3-aa741a74d652 (TCGA-BP-4758.F44EDB3A-BB3E-4F47-9577-C97C29E2017D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).